Surgical pathology report (de-identified scan), TCGA case TCGA-V9-A7HT, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-V9-A7HT-01A (Primary Tumor).

[page 1 of 2]
Surgical Final Report

Temporary Copy

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

Patient: [REDACTED]

ID: [REDACTED]

Location: [REDACTED]

Final Pathologic Diagnosis

RIGHT KIDNEY (LAPAROSCOPIC NEPHRECTOMY):

- Renal cell carcinoma, papillary type (8.0 cm), Fuhrman nuclear grade 3 (See synoptic report).

Note: The case was discussed in the _____ on _____ at _____ and reviewed in conjunction with one or more attending pathologists in this department who concur(s) with the above diagnosis.

I attest I have personally reviewed the specimen/slides and agree with the above findings.

Electronic Signature
Verified:

Resident:

ICD-O-3
Carcinoma, papillary renal cell
Site: @ Kidney NOS
8260/3
Q64.9

Synoptic Report

A: KIDNEY, NEPHRECTOMY

SPECIMEN TYPE:

Radical nephrectomy

LATERALITY:

Right

*TUMOR SITE:

*Upper pole

FOCALITY:

Unifocal

TUMOR SIZE (largest tumor if multiple):

Greatest dimension: 8.0 cm

*Additional dimensions: 7.1 x 5.3 cm

MACROSCOPIC EXTENT OF TUMOR:

Tumor limited to kidney

HISTOLOGIC TYPE:

Papillary renal carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade):

G3: Nuclei very irregular, ~20 microns; nucleoli large and prominent

PRIMARY TUMOR (pT) PRIMARY TUMOR (pT):

pT2: tumor more than 7 cm in greatest dimension, limited to the kidney

REGIONAL LYMPH NODES:

pNX: cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Margins uninvolved by invasive carcinoma

ADRENAL GLAND:

[page 2 of 2]
Surgical Final Report

Temporary Copy

Case: [REDACTED]

Patient: [REDACTED]

Collected: [REDACTED]

ID: [REDACTED]

Ordered by: [REDACTED]

Location: [REDACTED]

Not present

*VENOUS (LARGE VESSEL) INVASION (V) (excluding renal vein and inferior vena cava):

*Absent

*LYMPHATIC INVASION (L):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Inflammation (type): chronic

*COMMENT(S):

- The tumor exhibits histologic features of type-2 papillary renal cell carcinoma.

Clinical History

Not provided.

Pre/Post-operative Diagnosis

Not provided.

Gross Anatomic Description

(Dictated by [REDACTED] on [REDACTED] Reviewed by [REDACTED])

Specimen received in one container.

Specimen: Designated "right kidney" is received in formalin labeled with the patient's name, MRN and "right kidney". A small piece of the mass was submitted for [REDACTED]. Specimen consists of a right total nephrectomy weighing 284 g and measuring 12.2 x 6.7 x 6.2 cm. There is a portion of pericapsular fat around the hilum, superior pole and inferior pole measuring 0.5 cm in thickness.

Extending from the renal pelvis are a ureter (1.0 cm in length and 0.2 cm in diameter), renal artery (0.9 cm in length and 0.2 cm in diameter) and the renal vein cannot be definitely identified. Tumor does not extend into the ureter / artery and is not present at the resection margin. There is a 8.0 x 7.1 x 5.3 cm well circumscribed, solid, yellow/tan mass without necrosis and hemorrhage in the superior pole. It is 0.1 cm from the renal pelvis. The mass is confined in the renal capsule and does not invade the perinephric fat. However, there is possible extension of the mass into the calyces. The uninvolved renal parenchyma is tan/brown with a well defined corticomedullary junction, orderly particle striations and medullary raise. The pelvis and calyces appear smooth and gray/white. No adrenal gland is identified. No lymph nodes or stones are identified. Gross photographs are taken.

Inking code: Green – entire specimen.

Section code: A1 – ureter, renal artery and possible renal vein resection margins, en face; A2 – mass with nearest perinephric fat margin; A3 – mass with pelvis and adjacent renal parenchyma; A4 – additional section of renal pelvis; A5-A7 – additional sections of tumor; A8 – additional section of mass with renal pelvis; A9 – uninvolved kidney including renal parenchyma and pelvis.

Case is (a) (b) (c) (d) (e) (f) (g) (h) (i) (j) (k) (l) (m) (n) (o) (p) (q) (r) (s) (t) (u) (v) (w) (x) (y) (z)	QUALIFIED	DISQUALIFIED
Reviewed (initials)	8/31/13	8/30/13

Source: NCI Genomic Data Commons file cc841e9a-bf42-4850-9c24-525fc778db6d (TCGA-V9-A7HT.4043D1BE-FCA1-4613-B304-2B490FCBB6B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).